Surgical pathology report (de-identified scan), TCGA case TCGA-22-4595, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-22-4595-01A (Primary Tumor).

Surgical Pathology

TISSUE DESCRIPTION:

Left lower lobe lung (330 grams, 17 x 17 x 6 cm); portion of left lung lingula (8.5 x 4.5 x 2.2 cm); aortic (aortopulmonary), inferior mediastinal (subcarinal, inferior pulmonary ligament) and left fissure lymph nodes

DIAGNOSIS:

Lung, left lower lobe, lobectomy: Invasive grade 4 (of 4) squamous cell carcinoma forming a 6cm mass in the lower lobe extending through the pleura to involve mediastinal fat. The margins of resection, including the bronchial margin, are free of involvement.

Lymph nodes, intrapulmonary peribronchial, excision: Multiple (5 of 6) lymph nodes are involved by metastatic squamous cell carcinoma.

Lymph nodes, aortic, inferior mediastinal and left fissure, excision: Multiple inferior mediastinal lymph nodes (1 of 3 subcarinal, 1 of 3 inferior pulmonary ligament) are involved by metastatic squamous cell carcinoma. Multiple aortic (3 aortopulmonary) lymph nodes as well as a single left fissure lymph node are negative for tumor.

Lung, left lingula, excision: Lung parenchyma without diagnostic abnormalities.

Source: NCI Genomic Data Commons file e98875f6-2c8e-4709-94f6-99e2bb81586b (TCGA-22-4595.797AD94E-B3D2-44A4-8412-D8361A58BCD5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).